Somatic mutation profile of tumor specimen TCGA-80-5607-01A (aliquot TCGA-80-5607-01A-31D-1945-08) from TCGA case TCGA-80-5607, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-80-5607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b7a0b2a-d183-4ea9-a938-3542e279457e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-80-5607-10A (Blood Derived Normal), aliquot TCGA-80-5607-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1140a1ab-bec5-4884-bf42-ec7eb80756dd

The open-access MAF lists 134 somatic variants for this specimen: 102 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 28, Nonsense Mutation 14, Splice Site 2, Intron 2, Frame Shift Ins 2, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- KMT2D | c.12592C>T p.R4198* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as rs587783685, CM122102, COSV56409006, COSV56429446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALG10 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV56792276; called by muse, mutect2, varscan2
- ALMS1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52508185; called by muse, mutect2, varscan2
- ALPK2 | c.6153G>C p.L2051F | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV64492330; called by muse, varscan2
- ARFGEF1 | c.3238C>T p.L1080F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51606894; called by muse, mutect2, varscan2
- ASXL3 | c.3116C>G p.T1039S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1409647973, COSV52463659; called by muse, varscan2
- ATAD5 | c.4424T>G p.L1475* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | catalogued as COSV58973796; called by muse, mutect2, varscan2
- ATG4D | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV57264298; called by muse, mutect2, varscan2
- ATM | c.8875G>C p.D2959H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV53739395, COSV53745096, COSV99587492; called by muse, mutect2, varscan2
- BAZ2B | c.1421C>A p.T474K | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV58599274; called by muse, mutect2, varscan2
- CA3 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV53409732; called by muse, mutect2, varscan2
- CCDC88A | c.5308G>A p.A1770T (on ENST00000436346 / NM_001365480.1; = p.A1742T on NM_018084.5) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV55060295; called by muse, mutect2, varscan2
- CD163L1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.954); catalogued as rs1372828364, COSV58011979; called by muse, mutect2, varscan2
- CDH12 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV66399755; called by muse, mutect2, varscan2
- CDH12 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66399759; called by muse, mutect2, varscan2
- CDH13 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV51811597; called by muse, mutect2, varscan2
- CHAF1A | c.1007G>C p.R336T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs377259547; called by muse, mutect2, varscan2
- CHST5 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs577930949, COSV60338664; called by muse, mutect2, varscan2
- CLUL1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV58111835; called by muse, mutect2
- CNIH1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV53594390; called by muse, mutect2, varscan2
- CRYZL1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV51677110; called by muse, mutect2, varscan2
- CTDSPL2 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV52945791; called by muse, mutect2, varscan2
- CTNND2 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1037334305, COSV58882509; called by muse, mutect2, varscan2
- DNAH3 | c.11521G>A p.E3841K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.243); catalogued as rs752490065, COSV54516811; called by muse, mutect2, varscan2
- DNAH7 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV56760869; called by muse, mutect2, varscan2
- DUSP5 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV63645678; called by muse, mutect2, varscan2
- EPHA8 | c.2873C>G p.S958C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51266607; called by muse, mutect2, varscan2
- EPN2 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV59060917; called by muse, mutect2, varscan2
- FLNC | c.4818G>C p.M1606I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57954552; called by muse, mutect2, varscan2
- FREM2 | c.9192G>C p.E3064D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54835294, COSV54852408; called by muse, mutect2
- GPRC6A | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59952688; called by muse, mutect2, varscan2
- HECTD1 | c.5248G>C p.E1750Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.932); catalogued as COSV67945960; called by muse, mutect2, varscan2
- HELQ | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as COSV55024918; called by muse, mutect2, varscan2
- HIVEP2 | c.5861C>G p.P1954R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1483205041, COSV50009336; called by muse, mutect2, varscan2
- HSPA1L | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.073); catalogued as COSV65149001; called by muse, mutect2, varscan2
- IFIH1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV55126253, COSV55127391; called by muse, mutect2, varscan2
- IFNGR1 | c.547-1G>C p.X183_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV62989725; called by muse, mutect2
- KCNC1 | c.1450C>G p.Q484E | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as rs376505218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL41 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52929921; called by muse, mutect2, varscan2
- LPA | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 139/599 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as rs757112211, COSV60295974; called by muse, mutect2, varscan2
- MAGEA3 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV64755998; called by muse, mutect2, varscan2
- MAPRE2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV55818641; called by muse, mutect2, varscan2
- MARK2 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59282603; called by muse, mutect2, varscan2
- MTMR7 | c.983C>G p.S328* | Nonsense Mutation (SNP) | VAF 108/520 reads (21%) | catalogued as COSV51665225; called by muse, mutect2, varscan2
- NCKAP5 | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs368039458; called by muse, mutect2, varscan2
- NRIP1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as rs963720207, COSV59656833; called by muse, mutect2
- NUMA1 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV61184880; called by muse, mutect2, varscan2
- OR51E2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV67807271; called by muse, mutect2, varscan2
- OR5B3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.1); catalogued as rs372105081; called by muse, mutect2, varscan2
- OR8K1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54402220, COSV54402616; called by muse, mutect2, varscan2
- PCDHA3 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63540622; called by muse, mutect2, varscan2
- PCDHB3 | c.772A>G p.N258D | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV50569751; called by muse, mutect2, varscan2
- PCDHGB6 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1317609642, COSV53932852; called by muse, mutect2, varscan2
- PGGT1B | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs767299766, COSV56973732; called by muse, mutect2
- PIH1D1 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV51806810; called by muse, mutect2, varscan2
- PKD2L1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372584640, COSV58395621; called by muse, mutect2, varscan2
- PLCXD3 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs376668812; called by muse, mutect2, varscan2
- PLXNA1 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.166); catalogued as rs746756931, COSV52525199; called by muse, mutect2, varscan2
- PPARGC1B | c.2807G>C p.R936T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV58528575; called by muse, mutect2, varscan2
- PTDSS1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV61264429; called by muse, mutect2, varscan2
- PTPRN2 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV67033529; called by muse, mutect2, varscan2
- RAI1 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 28/165 reads (17%) | catalogued as COSV55392179; called by muse, mutect2, varscan2
- RASGRF1 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV101369632; called by muse, mutect2, varscan2
- RFX7 | c.4025C>T p.S1342F (on ENST00000559447 / NM_001368074.1; = p.S1439F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV57962539, COSV57966396; called by muse, mutect2, varscan2
- RPH3A | c.357G>C p.K119N (on ENST00000389385 / NM_001143854.2; = p.K115N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV66990783; called by muse, mutect2, varscan2
- SAE1 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1170179062, COSV54294481; called by muse, mutect2, varscan2
- SCN10A | c.5833G>T p.E1945* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV71860380, COSV71861055; called by muse, mutect2, varscan2
- SCN7A | c.4063C>T p.H1355Y | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs752225610, COSV69270844; called by muse, mutect2, varscan2
- SERPINA7 | c.458T>A p.L153H | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59665558; called by muse, mutect2, varscan2
- SETD2 | c.7239-2A>T p.X2413_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV57434559; called by muse, mutect2, varscan2
- SIGLEC1 | c.2797G>C p.D933H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52462202, COSV99163175; called by muse, mutect2, varscan2
- SLC35A5 | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV53726594; called by muse, mutect2, varscan2
- SLCO4A1 | c.1989G>A p.M663I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs762273150, COSV53890422, COSV53890917; called by muse, mutect2, varscan2
- SNX8 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV56126405; called by muse, mutect2, varscan2
- SNX9 | c.875G>A p.W292* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV67583925; called by muse, mutect2, varscan2
- SP1 | c.514C>T p.Q172* (on ENST00000327443 / NM_138473.3; = p.Q165* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as COSV59402551; called by muse, mutect2, varscan2
- SPHKAP | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV60875852; called by muse, mutect2, varscan2
- SPTAN1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV63986647; called by muse, mutect2, varscan2
- STOX2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV57851236, COSV57856285; called by muse, mutect2
- SYNE2 | c.10022C>G p.S3341* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV59939320; called by muse, mutect2, varscan2
- TAGLN2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV57422097; called by muse, mutect2, varscan2
- TARS2 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as rs778879320, COSV60872725; called by muse, mutect2, varscan2
- TMEM132B | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54745668, COSV54751321; called by muse, mutect2, varscan2
- TMPO | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV58461365; called by muse, mutect2, varscan2
- TNN | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53425078; called by muse, mutect2, varscan2
- TNS1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50698983, COSV99410886; called by muse, mutect2, varscan2
- UMODL1 | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs757646299, COSV61159867; called by muse, mutect2, varscan2
- URB2 | c.4337C>T p.S1446F | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50985624; called by muse, mutect2, varscan2
- USP26 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV63708521, COSV63708742; called by muse, mutect2, varscan2
- USP42 | c.1779G>A p.M593I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV60359464; called by muse, mutect2
- YME1L1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 55/211 reads (26%) | catalogued as COSV58759068; called by muse, mutect2, varscan2
- ZMIZ1 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs781519303, COSV57894136; called by muse, mutect2, varscan2
- ZNF318 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs1440028156, COSV58931991; called by muse, mutect2, varscan2
- ZNF382 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.973); catalogued as COSV53087727, COSV53088504; called by muse, mutect2, varscan2
- IGBP1P2 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PNISR | c.1397dup p.L466Ffs*12 | Frame Shift Ins (INS) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- RBP3 | c.1894T>G p.F632V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERPIND1 | c.344_385del p.Q115_I128del | In Frame Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel
- SF1 | c.1381dup p.Y461Lfs*151 | Frame Shift Ins (INS) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.2517C>T p.F839= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV51674755; called by muse, mutect2, varscan2
- ALPK2 | c.6099G>C p.L2033= | Silent (SNP) | VAF 46/214 reads (21%) | catalogued as COSV64492339; called by muse, varscan2
- BAG6 | c.2625C>T p.I875= (on ENST00000676571; = p.I828= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/226 reads (21%) | catalogued as COSV52989811; called by muse, mutect2, varscan2
- BAHD1 | c.970C>T p.L324= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV69083841; called by muse, mutect2, varscan2
- C1QL4 | c.24C>T p.A8= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV57743762; called by muse, mutect2, varscan2
- CCKAR | c.1095C>A p.V365= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs201916972, COSV55161051; called by muse, mutect2, varscan2
- COCH | c.1578A>C p.I526= (on ENST00000216361 / NM_001347720.1; = p.I461= on NM_004086.3) | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV53550571; called by muse, mutect2, varscan2
- CUL4B | c.1065G>A p.E355= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV60686815; called by muse, mutect2, varscan2
- DENND1A | c.1248G>A p.L416= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV65324720; called by muse, mutect2, varscan2
- GPATCH8 | c.1569G>A p.G523= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs149798216; called by muse, mutect2, varscan2
- GPRC6A | c.1506C>T p.I502= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV59952680; called by muse, varscan2
- INSYN2A | c.168G>A p.Q56= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as COSV54737192; called by muse, mutect2, varscan2
- KCNF1 | c.891C>T p.I297= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs559871658, COSV54462612; called by muse, mutect2, varscan2
- KIR3DL3 | c.879C>T p.C293= | Silent (SNP) | VAF 51/274 reads (19%) | catalogued as COSV52549085; called by muse, mutect2, varscan2
- MARF1 | c.3333G>C p.L1111= | Silent (SNP) | VAF 57/230 reads (25%) | catalogued as COSV60022541; called by muse, mutect2, varscan2
- MARK2 | c.789G>A p.L263= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as COSV59282619; called by muse, mutect2, varscan2
- MIEF1 | c.822C>T p.I274= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV57478637; called by muse, mutect2, varscan2
- MSH5 | c.474C>T p.A158= | Silent (SNP) | VAF 50/748 reads (7%) | catalogued as rs747523953, COSV65209415; called by muse, mutect2
- PAQR7 | c.495C>T p.A165= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs1302869467, COSV65351614; called by muse, mutect2, varscan2
- PCDHB11 | c.1500C>T p.L500= | Silent (SNP) | VAF 84/342 reads (25%) | catalogued as rs561828114, COSV61311088; called by muse, mutect2, varscan2
- PHF20 | c.777A>G p.K259= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV59185670; called by muse, mutect2, varscan2
- PTX4 | c.438G>A p.Q146= (on ENST00000447419 / NM_001328608.2; = p.Q141= on NM_001013658.1) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53515547; called by muse, mutect2, varscan2
- RASGRF1 | c.1254G>A p.E418= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs769459245, COSV101369633; called by muse, varscan2
- SETBP1 | c.1401G>A p.L467= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs769626940, COSV56319627; called by muse, mutect2, varscan2
- SLC9A9 | c.525C>T p.I175= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs377682237, COSV57239329; called by muse, mutect2, varscan2
- SP140 | c.1620T>C p.N540= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV59448721; called by muse, mutect2, varscan2
- TEX2 | c.2061C>G p.L687= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs370141908, COSV51980246; called by muse, mutect2, varscan2
- TLE4 | c.15G>T p.L5= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99512126; called by muse, mutect2, varscan2
- DUSP13 | c.*245G>A | 3'UTR (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100403468; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86000C>G | Intron (SNP) | VAF 42/191 reads (22%) | catalogued as COSV72276627; called by muse, mutect2, varscan2
- OR2U1P | n.198C>G | RNA (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- VPS13B | c.4820+15669G>C | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as COSV62139272; called by muse, mutect2, varscan2
